Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6480, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6480-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1-2) TONSIL, RIGHT, EXCISIONAL BIOPSIES: MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA, EXTENDING TO TISSUE EDGES (SEE COMMENT).

COMMENT: HPV testing has been requested, and results will be reported separately.

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)right tonsil; 2)right tonsil #2

Instructions to Pathologist: #1 - frozen; #2 - please test for HPV

GROSS DESCRIPTION:

1) SOURCE: Right Tonsil

The specimen is received fresh in a container labeled with the patient's name, medical record number, and "right tonsil". The specimen consists of multiple tan to white fragments measuring 0.5 x 0.3 x 0.2 cm in aggregate.

All the tissue is submitted for frozen section.

Summary of sections: 1AFSC, M/1.

2) SOURCE: Right Tonsil #2

The specimen is received fresh in a container labeled with the patient's name, medical record number, and "right tonsil permanent". The specimen consists of two tan-white fragments of tissue measuring in aggregate 1.8 x 0.7 x 0.3 cm. The entire specimen is submitted.

Summary of sections: 2A, tissue, 2/1.

[page 2 of 2]
Dictated by [REDACTED]
[REDACTED]

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Right Tonsil

FROZEN SECTION DIAGNOSIS: AT LEAST SQUAMOUS CELL CARCINOMA IN SITU. [REDACTED] [REDACTED]

Electronically signed by: [REDACTED]

[REDACTED] [REDACTED]

Source: NCI Genomic Data Commons file 494a67a6-cad8-4415-9a32-76fbceb1454c (TCGA-CR-6480.8F3DDC8B-446E-44BE-A5A3-638FEA151944.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).